Somatic mutation profile of tumor specimen C3N-02062-03 (aliquot CPT0134500006) from CPTAC case C3N-02062, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 67.7 years (24,730 days).
Specimen C3N-02062-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 029cf27c-81e2-4055-b4c4-c7819136c9c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02062-71 (Blood Derived Normal), aliquot CPT0134600002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d7311e3-3495-4ca7-aa39-de5f36017548

The open-access MAF lists 81 somatic variants for this specimen: 67 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 10, Frame Shift Del 5, Nonsense Mutation 5, Intron 3, Splice Site 1, In Frame Del 1, 3'UTR 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 47/125 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1137A>C p.K379N (on ENST00000521381 / NM_181523.3; = p.K109N on NM_181504.4) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57132536; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 56/180 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 263/729 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as rs55832599, CM120851, COSV52678166, COSV52736883, COSV52827473; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ZBTB7A | c.1272G>T p.K424N | Missense Mutation (SNP) | VAF 116/344 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59326106; called by muse, mutect2, varscan2
- ARID1A | c.6762C>G p.Y2254* | Nonsense Mutation (SNP) | VAF 60/170 reads (35%) | catalogued as COSV61373199, COSV61374456; called by muse, mutect2, varscan2
- ATP2B3 | c.2767C>T p.R923C | Missense Mutation (SNP) | VAF 220/635 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs141643926, COSV99684303, COSV99685610; called by muse, mutect2, varscan2
- CANT1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 331/860 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs747973861, COSV56606137; called by muse, mutect2, varscan2
- CCAR2 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 257/712 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as rs770017667; called by muse, mutect2, varscan2
- CDH10 | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 166/533 reads (31%) | catalogued as COSV52589706; called by muse, mutect2, varscan2
- CEP95 | c.2122C>T p.R708* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as rs782719413, COSV73609504; called by muse, mutect2, varscan2
- CRAMP1 | c.2369G>A p.R790H | Missense Mutation (SNP) | VAF 77/191 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs773417565, COSV99245654; called by muse, mutect2, varscan2
- CSMD1 | c.8485A>G p.K2829E (on ENST00000520002; = p.K2828E on NM_033225.6) | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.987); catalogued as rs771453442; called by muse, mutect2, varscan2
- DNAH10 | c.4972G>A p.D1658N (on ENST00000409039; = p.D1597N on NM_207437.3) | Missense Mutation (SNP) | VAF 90/229 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745454517, COSV68994234; called by muse, mutect2, varscan2
- DPYSL2 | c.1507G>A p.V503M | Missense Mutation (SNP) | VAF 127/285 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs781441381; called by muse, mutect2, varscan2
- DZIP3 | c.2249G>T p.R750M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV100847984; called by muse, mutect2, varscan2
- EPHA1 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 326/830 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs140233341; called by muse, mutect2, varscan2
- ERVW-1 | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 84/254 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs762644633; called by muse, mutect2, varscan2
- FAM171A1 | c.2348C>T p.T783M | Missense Mutation (SNP) | VAF 60/329 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.643); catalogued as rs1250457447; called by muse, mutect2, varscan2
- FRMD6 | c.1108G>A p.G370R (on ENST00000344768 / NM_001267046.2; = p.G362R on NM_152330.4) | Missense Mutation (SNP) | VAF 179/451 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs774320055, COSV61091253; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1285_1287del p.E429del | In Frame Del (DEL) | VAF 168/592 reads (28%) | catalogued as rs1219094648; called by pindel, varscan2
- GPR27 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 123/267 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.107); catalogued as rs373590635; called by muse, mutect2, varscan2
- ITIH6 | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs778196393, COSV54489223; called by muse, mutect2, varscan2
- JPH2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 246/562 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as rs774653018, COSV100881576, COSV65901973; called by muse, mutect2, varscan2
- NCALD | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 21/399 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1212404446, COSV99637596; called by muse, mutect2
- NRDC | c.3008C>T p.T1003M | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.488); catalogued as rs149391175; called by muse, mutect2, varscan2
- OR4Q2 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs983631004, COSV73406224; called by muse, mutect2, varscan2
- PIK3R1 | c.1722A>C p.R574S (on ENST00000521381 / NM_181523.3; = p.R304S on NM_181504.4) | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV99073793; called by muse, mutect2, varscan2
- POP1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 119/353 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as rs1169492285, COSV62893158; called by muse, mutect2, varscan2
- PTEN | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD993696, COSV64289071, COSV64293681, COSV64309763; called by muse, varscan2
- PTEN | c.528T>A p.Y176* | Nonsense Mutation (SNP) | VAF 46/109 reads (42%) | catalogued as CM020756, CM033668, CX135246, COSV64292861; called by muse, mutect2, varscan2
- RBFOX1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 89/221 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV60952754; called by muse, mutect2, varscan2
- REM1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 295/734 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs149687528; called by muse, mutect2, varscan2
- RPS6KA4 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 108/243 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750338757, COSV53700892; called by muse, mutect2, varscan2
- SLITRK1 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 111/294 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV65677589; called by muse, mutect2, varscan2
- SNURF | c.19C>A p.R7S | Missense Mutation (SNP) | VAF 146/463 reads (32%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.254); catalogued as COSV57596075, COSV57597173, COSV57599420; called by muse, mutect2, varscan2
- SPPL3 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs776981621; called by muse, mutect2, varscan2
- SYT8 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 141/327 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs751166451; called by muse, mutect2, varscan2
- VEPH1 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 119/368 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377432189, COSV62878916; called by muse, mutect2, varscan2
- ZNF462 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as rs1199651465; called by muse, mutect2
- ANKS1B | c.142C>G p.R48G | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARID1A | c.2180_2186del p.R727Pfs*13 | Frame Shift Del (DEL) | VAF 124/314 reads (39%) | called by mutect2, pindel, varscan2
- CFP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 287/733 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CLN5 | c.374del p.T125Nfs*2 | Frame Shift Del (DEL) | VAF 57/183 reads (31%) | called by mutect2, pindel, varscan2
- CTCF | c.1601del p.Q534Rfs*50 | Frame Shift Del (DEL) | VAF 148/416 reads (36%) | called by mutect2, pindel, varscan2
- DDX3X | c.762G>C p.K254N (on ENST00000399959; = p.K255N on NM_001356.5) | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- EPRS1 | c.1398G>T p.M466I | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- FSIP2 | c.10999C>T p.L3667F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HCFC1 | c.875G>A p.C292Y | Missense Mutation (SNP) | VAF 196/474 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1210 | c.5002G>A p.E1668K | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- LILRA6 | c.865T>A p.S289T | Missense Mutation (SNP) | VAF 346/1805 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MAP3K1 | c.3667-1G>A p.X1223_splice | Splice Site (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- MTERF1 | c.499T>C p.F167L | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NTF4 | c.583A>G p.I195V | Missense Mutation (SNP) | VAF 155/370 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PCDHA6 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 295/862 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PIK3CD | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 26/563 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); called by muse, mutect2
- SLC1A6 | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 145/359 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC38A2 | c.1130T>A p.L377Q | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- SMARCA5 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SNAPC5 | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 30/441 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); called by muse, mutect2
- SPTLC3 | c.1567del p.M523Wfs*7 | Frame Shift Del (DEL) | VAF 53/167 reads (32%) | called by mutect2, pindel, varscan2
- STXBP5 | c.1288A>C p.K430Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); called by muse, mutect2
- TACC2 | c.3490C>G p.H1164D | Missense Mutation (SNP) | VAF 131/302 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TARS3 | c.2386C>T p.L796F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.702); called by muse, varscan2
- TNRC6B | c.3282dup p.F1095Ifs*2 (on ENST00000454349 / NM_001162501.2; = p.F1042Ifs*2 on NM_015088.3) | Frame Shift Ins (INS) | VAF 33/89 reads (37%) | called by mutect2, pindel, varscan2
- ZNF174 | c.1105del p.L369* | Frame Shift Del (DEL) | VAF 167/533 reads (31%) | called by mutect2, pindel, varscan2
- ZNF354C | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 46/104 reads (44%) | called by muse, mutect2, varscan2
- AWAT2 | c.432T>C p.F144= | Silent (SNP) | VAF 93/240 reads (39%) | called by muse, mutect2, varscan2
- EHBP1L1 | c.4248C>T p.N1416= | Silent (SNP) | VAF 131/451 reads (29%) | catalogued as rs113817256, COSV100442235; called by muse, mutect2, varscan2
- GABBR2 | c.957C>T p.F319= | Silent (SNP) | VAF 198/530 reads (37%) | catalogued as rs768785875, COSV52293529; called by muse, mutect2, varscan2
- GRIA3 | c.396C>T p.D132= | Silent (SNP) | VAF 212/560 reads (38%) | catalogued as rs192636764, COSV99989640; called by muse, mutect2, varscan2
- NDST1 | c.1686C>T p.P562= | Silent (SNP) | VAF 107/257 reads (42%) | called by muse, mutect2
- NDUFAF1 | c.513G>T p.A171= | Silent (SNP) | VAF 109/296 reads (37%) | called by muse, mutect2, varscan2
- RIN1 | c.501C>T p.H167= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as rs143847360; called by muse, mutect2, varscan2
- SLC4A4 | c.1752G>A p.T584= (on ENST00000264485 / NM_001098484.3; = p.T540= on NM_003759.4) | Silent (SNP) | VAF 47/121 reads (39%) | catalogued as rs747153129, COSV99138936; called by muse, mutect2, varscan2
- SPANXN4 | c.294G>A p.Q98= | Silent (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- WDR97 | c.4650C>T p.S1550= | Silent (SNP) | VAF 22/505 reads (4%) | called by muse, mutect2
- LHB | c.*33G>A | 3'UTR (SNP) | VAF 75/520 reads (14%) | catalogued as rs774432143; called by muse, mutect2, varscan2
- NEIL1 | c.435-794C>G | Intron (SNP) | VAF 47/118 reads (40%) | called by muse, mutect2, varscan2
- SLC25A25 | c.262-9169C>T | Intron (SNP) | VAF 90/240 reads (38%) | catalogued as rs762611855; called by muse, mutect2, varscan2
- ZDHHC11 | c.1023+1113C>T | Intron (SNP) | VAF 73/219 reads (33%) | catalogued as rs758699080; called by muse, mutect2, varscan2
